Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4991, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4991-01A (Primary Tumor).

[page 1 of 2]
Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

TCGA - BP - 4991

Clinical Diagnosis & History:

with right renal mass.

Specimens Submitted:

1: SP: Kidney, right upper pole, partial nephrectomy

DIAGNOSIS:

1. SP: Kidney, right upper pole, partial nephrectomy

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade I/IV

Tumor Size:

Greatest diameter is 2.5 cm.

Local Invasion (for renal cortical types):

Not Identified

Renal Vein Invasion:

Not Identified

Small vessel invasion is also not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Mild arteriosclerosis

Adrenal Gland:

Not Identified

Lymph Nodes:

Not Identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor <= 7.0 cm in greatest dimension limited to the kidney

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[page 2 of 2]
Gross Description:

1). The specimen is received fresh for frozen section, labeled "right upper pole renal tumor stitch marks deep margin". It consists of 6 x 5.5 x 4 cm wedge shaped portion of kidney with a suture marking the deep margin. The deep margin is inked black and soft tissue is inked blue. The specimen is serially sectioned to reveal a golden yellow 2.5 x 2.5 x 2 cm tumor. The clearance from the resection margin is 0.3 cm. A representative section of the nearest margin is submitted for frozen section diagnosis. The tumor is entirely submitted. Portions of the tumor are submitted for TPS.

Summary of sections:

FSC - frozen section control

T - tumor

RS - representative sections

Summary of Sections:

Part 1: SP: Kidney, right upper pole, partial nephrectomy

Block	Sect. Site	PCs
1	fsc	1
1	rs	1
3	t	3

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: RENAL CELL CARCINOMA, MARGINS ARE FREE OF TUMOR. CLOSEST FREE MARGIN IS WITHIN 0.2 CM.
PERMANENT DIAGNOSIS: SAME

Source: NCI Genomic Data Commons file 262f1010-8c9f-455c-9df8-a0aacad0c680 (TCGA-BP-4991.C80790ED-8ADF-4A0D-A9F5-736ABD7C7DE5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).